Somatic mutation profile of tumor specimen TCGA-YL-A8SJ-01B (aliquot TCGA-YL-A8SJ-01B-11D-A377-08) from TCGA case TCGA-YL-A8SJ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.0 years (21,916 days).
Specimen TCGA-YL-A8SJ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eac88837-9521-4b69-97a6-15e40b5697e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SJ-10A (Blood Derived Normal), aliquot TCGA-YL-A8SJ-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c51868e6-3079-4c86-8501-21628c2ac35a

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.848T>A p.I283N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100047683; called by muse, mutect2, varscan2
- CADM1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100523361; called by muse, mutect2, varscan2
- CLDN20 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100905069; called by muse, mutect2, varscan2
- DNAH17 | c.9274G>A p.E3092K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748643058, COSV101103407; called by muse, varscan2
- FRMD5 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as COSV101296693; called by muse, mutect2, varscan2
- GALNT15 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007560281, COSV60216095; called by muse, mutect2
- GRM1 | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.687); catalogued as rs751274056, COSV51152965; called by muse, mutect2, varscan2
- ITPR2 | c.6357T>G p.N2119K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV101190154; called by muse, mutect2, varscan2
- MCC | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs749827179, COSV56729324; called by muse, mutect2, varscan2
- MOV10L1 | c.2275G>T p.G759C | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99435086; called by muse, mutect2
- NRAP | c.4196G>A p.W1399* (on ENST00000359988 / NM_001322945.2; = p.W1364* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs756886257, COSV100748595; called by muse, mutect2, varscan2
- OR11L1 | c.746C>G p.T249S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV100869488, COSV63313888; called by muse, mutect2, varscan2
- PFKFB1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 35/137 reads (26%) | catalogued as rs372795411, COSV66628173; called by muse, mutect2, varscan2
- PLB1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1361260257, COSV100579855; called by muse, mutect2, varscan2
- PMPCA | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs751214293, COSV100867842; called by muse, mutect2, varscan2
- SI | c.4666A>G p.R1556G | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017076; called by muse, mutect2, varscan2
- SRCAP | c.3331C>T p.P1111S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.241); catalogued as rs758974964, COSV99351284; called by muse, mutect2, varscan2
- TENM4 | c.7267G>T p.V2423L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99579006; called by muse, mutect2, varscan2
- TP53 | c.494_495insTGCT p.Q165Hfs*17 | Frame Shift Ins (INS) | VAF 17/55 reads (31%) | catalogued as COSV99451384; called by mutect2, pindel, varscan2
- WDFY3 | c.6918G>T p.E2306D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as rs1330739859, COSV99885563; called by muse, mutect2, varscan2
- CDSN | c.1095G>A p.S365= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs765478855, COSV99457232; called by muse, mutect2, varscan2
- IL1A | c.543C>T p.T181= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV54519017; called by muse, mutect2, varscan2
- NPTX2 | c.1143C>T p.R381= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs776156518, COSV55716965; called by muse, mutect2
- RBM12 | c.2791T>C p.L931= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100468076; called by muse, mutect2, varscan2
- SHOX2 | c.498C>T p.D166= (on ENST00000441443 / NM_006884.3; = p.D190= on NM_003030.4) | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV101273831, COSV67464599; called by muse, mutect2
- SMCR8 | c.831G>A p.Q277= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100329300; called by muse, mutect2, varscan2
- SYNE1 | c.153C>T p.D51= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs779081280, COSV55100780; called by muse, mutect2, varscan2
